Somatic mutation profile of tumor specimen TCGA-CM-6168-01A (aliquot TCGA-CM-6168-01A-11D-1650-10) from TCGA case TCGA-CM-6168, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.4 years (30,834 days).
Specimen TCGA-CM-6168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb01cbd-498e-4450-9e30-4ee1cdf9f087.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6168-10A (Blood Derived Normal), aliquot TCGA-CM-6168-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea4e0e56-2288-4f05-a57f-0ae3e92139c5

The open-access MAF lists 237 somatic variants for this specimen: 180 protein-altering or splice-affecting, 53 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 53, Nonsense Mutation 20, Frame Shift Del 13, Splice Site 3, Splice Region 3, Frame Shift Ins 3, RNA 2, Intron 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 35/198 reads (18%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CD40LG | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 35/220 reads (16%) | catalogued as rs193922135, CM980314, COSV65699150; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A1 | c.2085del p.G696Afs*106 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs606231464; ClinVar: pathogenic; called by mutect2, pindel
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 60/302 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 103/605 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SCN9A | c.2503C>T p.R835* (on ENST00000303354; = p.R824* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as rs1329907808, COSV57627514; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- SMO | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121918348, COSV50847709; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100750637; called by muse, mutect2, varscan2
- ABCD3 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV59866119; called by muse, mutect2
- ACACA | c.3764G>A p.S1255N | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as rs758156281; called by muse, mutect2
- ADCK5 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs199670913, COSV100450309; called by muse, mutect2, varscan2
- ALDH1L2 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51555115; called by muse, mutect2
- ALPK2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as COSV64498037; called by muse, mutect2, varscan2
- AMER1 | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100365705; called by muse, mutect2, varscan2
- AMHR2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746307025, COSV57686845; called by muse, mutect2, varscan2
- AMOT | c.1654_1656del p.E552del (on ENST00000371959 / NM_001113490.1; = p.E143del on NM_133265.3) | In Frame Del (DEL) | VAF 31/218 reads (14%) | catalogued as rs774599150; called by mutect2, pindel, varscan2
- ANKLE1 | c.1316G>A p.R439K (on ENST00000394458; = p.R385K on NM_152363.6) | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs1314590852, COSV100845718, COSV63920358; called by muse, mutect2, varscan2
- APC | c.4396G>T p.G1466* | Nonsense Mutation (SNP) | VAF 33/174 reads (19%) | catalogued as COSV57320499, COSV57342796; called by muse, mutect2, varscan2
- APOB | c.9061C>A p.H3021N | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99264676; called by muse, mutect2, varscan2
- ARHGAP36 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52273271; called by muse, mutect2, varscan2
- ARMC3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769301977, COSV53068869; called by mutect2, varscan2
- ATG9B | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV52511371; called by muse, mutect2, varscan2
- ATP11A | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1009070726, COSV99369776; called by muse, mutect2
- AUTS2 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs200108105, COSV61433350; called by muse, mutect2, varscan2
- BMP10 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as rs767877244, COSV54896262; called by muse, mutect2, varscan2
- C15orf39 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs939534001, COSV62297475; called by muse, mutect2, varscan2
- C7orf61 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV55725647; called by muse, mutect2, varscan2
- CACNA1E | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 96/515 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs373195246; called by muse, mutect2, varscan2
- CACNA1I | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359726; called by muse, mutect2, varscan2
- CACNA1S | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143722841; called by muse, mutect2, varscan2
- CACNA2D1 | c.1114A>G p.I372V | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.141); catalogued as rs1467730798, COSV62394948; called by muse, mutect2
- CASR | c.1630del p.V544Cfs*6 (on ENST00000490131; = p.V621Cfs*6 on NM_000388.4) | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | catalogued as COSV56135367, COSV56142063; called by mutect2, pindel, varscan2
- CATSPERD | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200349808, COSV100486725; called by muse, mutect2, varscan2
- CCDC62 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs746880817, COSV53437170; called by muse, mutect2, varscan2
- CCSER2 | c.109A>T p.N37Y | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV56505084, COSV99825693; called by muse, mutect2, varscan2
- CDH12 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101201986; called by muse, mutect2, varscan2
- CDK1 | c.424A>T p.I142F | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100358793; called by muse, mutect2
- CDK5RAP2 | c.3595C>A p.L1199M | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV62578071; called by muse, mutect2, varscan2
- CELA2B | c.639+1G>A p.X213_splice | Splice Site (SNP) | VAF 11/85 reads (13%) | catalogued as rs202010806, COSV65546429; called by muse, mutect2, varscan2
- CHRD | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52613339; called by muse, mutect2, varscan2
- CNOT11 | c.678C>T p.A226= | Splice Region (SNP) | VAF 65/339 reads (19%) | catalogued as rs754127343, COSV56820200; called by muse, mutect2, varscan2
- COL19A1 | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1266313478, COSV59579518, COSV59585179; called by muse, mutect2, varscan2
- COL6A5 | c.7538C>A p.P2513H (on ENST00000312481; = p.P2509H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV55218391; called by muse, mutect2
- CPO | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as rs370230012; called by muse, mutect2, varscan2
- CPSF1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554866754, COSV100574308; called by muse, mutect2, varscan2
- CREBBP | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV99269242; called by muse, mutect2, varscan2
- CTR9 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775811515, COSV63728913; called by muse, mutect2, varscan2
- DAPK1 | c.2854C>T p.R952* | Nonsense Mutation (SNP) | VAF 16/233 reads (7%) | catalogued as rs749723265, COSV63791601; called by muse, mutect2
- DHX15 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754378482, COSV61027175; called by muse, mutect2, varscan2
- DLGAP1 | c.1062A>C p.E354D | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV59841290; called by muse, mutect2, varscan2
- DOCK5 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs768684765, COSV99376505; called by muse, mutect2, varscan2
- DPPA4 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59512777; called by muse, mutect2, varscan2
- DPY19L2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551277775, COSV60545900; called by muse, mutect2, varscan2
- EBPL | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as rs200901347, COSV54431481; called by mutect2, varscan2
- FAM180A | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV58529540; called by muse, varscan2
- FBXL18 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV66669143; called by muse, mutect2, varscan2
- FBXO22 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 67/458 reads (15%) | catalogued as COSV57616613; called by muse, mutect2, varscan2
- FNBP4 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 81/501 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV55452710; called by muse, mutect2, varscan2
- FREM2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV54835896; called by muse, mutect2, varscan2
- FYCO1 | c.393C>T p.T131= | Splice Region (SNP) | VAF 28/148 reads (19%) | catalogued as COSV56120540, COSV99946050; called by muse, mutect2, varscan2
- GAREM1 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99330397; called by muse, mutect2, varscan2
- GGT5 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs760699269, COSV54072966; called by muse, mutect2, varscan2
- GLIPR1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56993247; called by muse, mutect2, varscan2
- GNAQ | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54127348; called by muse, mutect2, varscan2
- GNB4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs755864696, COSV51708924; called by muse, mutect2, varscan2
- GRHL2 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.276); catalogued as COSV52556041; called by muse, mutect2, varscan2
- HCN1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs180790607, COSV57495369, COSV57501466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECW1 | c.2735G>C p.G912A | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV67841289, COSV67841662; called by muse, varscan2
- HECW1 | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV67841666; called by muse, varscan2
- HNRNPA1 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV52939163; called by muse, mutect2, varscan2
- HOXD4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754784160, COSV60461109; called by muse, mutect2, varscan2
- IFNA13 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747627050, COSV71924600; called by muse, mutect2, varscan2
- IGHV1-58 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.06); catalogued as rs1298622643; called by muse, mutect2
- IGSF3 | c.3001del p.R1001Gfs*34 (on ENST00000369486 / NM_001007237.3; = p.R1021Gfs*34 on NM_001542.4) | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | catalogued as COSV59591513; called by mutect2, pindel
- INO80B | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99270385; called by muse, mutect2, varscan2
- IVL | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as COSV64217390; called by muse, mutect2, varscan2
- KLK4 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs777659052, COSV100133555; called by muse, mutect2, varscan2
- KMT2C | c.11356T>A p.S3786T | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100069527; called by muse, mutect2, varscan2
- KMT2D | c.7475G>T p.G2492V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56493247; called by muse, mutect2, varscan2
- KRTAP10-7 | c.992C>G p.P331R | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV59113894; called by muse, mutect2
- LARGE1 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as rs140257955; called by mutect2, varscan2
- MANBA | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs1474826955, COSV56971292; called by muse, mutect2, varscan2
- MAST3 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs748960066, COSV53227635, COSV99444309; called by muse, mutect2, varscan2
- MLXIPL | c.1259C>A p.P420Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as rs1554594709, COSV100515248; called by muse, mutect2, varscan2
- MON2 | c.3691A>G p.T1231A | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV54816529; called by muse, mutect2, varscan2
- MUC16 | c.21176A>G p.H7059R | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV101199094; called by muse, mutect2
- MUC5AC | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); catalogued as rs140943417, COSV62254462; called by muse, mutect2, varscan2
- MYO9A | c.6071A>G p.D2024G | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV100613004; called by muse, mutect2, varscan2
- NAGPA | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs1313603972, COSV56571085; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NCKAP1L | c.2376G>A p.W792* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV53213187; called by muse, mutect2, varscan2
- NFAM1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs927127417, COSV100216155, COSV61194677; called by muse, mutect2, varscan2
- NOS2 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as rs2314808, COSV58227884; called by muse, mutect2, varscan2
- NOTCH3 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354107566, COSV54653445; called by muse, mutect2, varscan2
- NR5A1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1185991537, COSV65295550; called by muse, mutect2, varscan2
- NT5C1A | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV52496733; called by muse, mutect2, varscan2
- OR2F1 | c.903G>A p.W301* | Nonsense Mutation (SNP) | VAF 32/301 reads (11%) | catalogued as rs1334524000, COSV101231297; called by muse, mutect2
- OR4F15 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 72/704 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1361535426, COSV59970556; called by muse, mutect2
- OR52K1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 51/254 reads (20%) | catalogued as rs763614886, COSV56904034; called by muse, mutect2, varscan2
- PCDHA7 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV100971341; called by muse, mutect2, varscan2
- PCDHB6 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.153); catalogued as rs782086754, COSV50707332; called by muse, mutect2, varscan2
- PCDHGA2 | c.1608C>A p.D536E | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54049732; called by muse, mutect2, varscan2
- PCDHGB7 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54049774; called by muse, mutect2, varscan2
- PCGF1 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV99283249; called by muse, mutect2
- PCNX2 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV50931486; called by muse, mutect2, varscan2
- PDE1B | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54489976; called by muse, mutect2
- PHC2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201814819; called by muse, mutect2, varscan2
- PLEC | c.9433C>T p.R3145* (on ENST00000322810 / NM_201380.4; = p.R3035* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1410984638, COSV100512380; called by muse, varscan2
- PLEC | c.7084C>T p.Q2362* (on ENST00000322810 / NM_201380.4; = p.Q2252* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as rs1554691714, COSV100512381; called by muse, mutect2
- PLEKHG6 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); catalogued as rs781352548, COSV99164131; called by muse, mutect2, varscan2
- PLXDC2 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.163); catalogued as COSV65909878; called by muse, mutect2, varscan2
- PMS1 | c.2101T>C p.F701L | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.699); catalogued as COSV59720797; called by muse, mutect2, varscan2
- PMS2 | c.2248G>T p.G750C | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56219547; called by muse, mutect2, varscan2
- PNOC | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV57284727; called by muse, mutect2, varscan2
- PREX2 | c.4061C>A p.P1354Q | Missense Mutation (SNP) | VAF 82/618 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55797512, COSV55803306; called by muse, varscan2
- PRIMPOL | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV59251140; called by muse, mutect2, varscan2
- PRMT3 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as rs376995112; called by mutect2, varscan2
- PROS1 | c.1283C>A p.A428E | Missense Mutation (SNP) | VAF 92/514 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV67775629, COSV67777609; called by muse, mutect2, varscan2
- PRPH | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs775233209, COSV57679955; called by muse, mutect2, varscan2
- PRX | c.3919C>T p.R1307W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752593001, COSV99396503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRO | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1271095110, COSV55505064; called by muse, mutect2
- RAVER2 | c.1141A>G p.M381V | Missense Mutation (SNP) | VAF 133/754 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV53811593; called by muse, mutect2, varscan2
- RCC2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64905819; called by muse, mutect2, varscan2
- RHBDD3 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99328464; called by muse, mutect2, varscan2
- RNF6 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 25/267 reads (9%) | catalogued as rs762149904, COSV60420780; called by muse, mutect2
- RSRP1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV54563444; called by muse, mutect2, varscan2
- SACS | c.9278T>C p.V3093A | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as rs1246419740, COSV101207273; called by muse, mutect2
- SCUBE1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs377327418; called by muse, mutect2, varscan2
- SEC24C | c.2303G>C p.G768A | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59545447; called by muse, mutect2, varscan2
- SEMA4C | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.183); catalogued as rs752887211, COSV100560823; called by mutect2, varscan2
- SLC18A3 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs867798275, COSV60326327; called by muse, mutect2, varscan2
- SLC44A4 | c.2011C>T p.L671= | Splice Region (SNP) | VAF 14/84 reads (17%) | catalogued as rs768032825, COSV57665844; called by muse, mutect2, varscan2
- SLC47A1 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV99565193; called by muse, mutect2, varscan2
- SLIT1 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759543634, COSV56600896; called by muse, mutect2, varscan2
- SMC2 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53965697; called by muse, mutect2, varscan2
- SNTG2 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | catalogued as COSV58009767; called by muse, mutect2, varscan2
- SNX1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as COSV56038389, COSV56040344; called by muse, mutect2, varscan2
- SNX12 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52146759; called by muse, mutect2, varscan2
- STPG2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs761770221, COSV54824116; called by muse, mutect2, varscan2
- SYTL1 | c.958G>A p.A320T (on ENST00000543823; = p.A308T on NM_032872.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV58874896; called by mutect2, varscan2
- TENT2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 135/645 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs549225169, COSV57134825; called by muse, mutect2, varscan2
- TENT4B | c.744G>T p.E248D (on ENST00000561678 / NM_001365323.2; = p.E233D on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs766033483, COSV62549715; called by muse, mutect2, varscan2
- THRB | c.1254G>C p.W418C | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769348, COSV99769595; called by muse, mutect2, varscan2
- TMEM184B | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.306); catalogued as rs1226129023; called by muse, mutect2
- TMEM256 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56658797; called by muse, mutect2, varscan2
- TMPRSS11F | c.947A>T p.D316V | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs758855490, COSV62469988; called by muse, mutect2, varscan2
- TNXB | c.12964C>T p.R4322C (on ENST00000647633; = p.R4075C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/498 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1562769769, COSV64491623; called by muse, varscan2
- TSNARE1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.56); catalogued as COSV56185183; called by muse, mutect2
- TSNAXIP1 | c.1335C>G p.I445M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.237); catalogued as COSV54652606; called by muse, mutect2, varscan2
- TTN | c.21173A>G p.N7058S (on ENST00000591111; = p.N6131S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/347 reads (20%) | PolyPhen benign (0.02); catalogued as COSV59892774; called by muse, mutect2, varscan2
- TUB | c.802C>T p.R268C (on ENST00000299506 / NM_177972.3; = p.R323C on NM_003320.4) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750902007, COSV55107856; called by muse, mutect2, varscan2
- USF3 | c.1469C>A p.P490Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV100324984; called by muse, mutect2
- VCPIP1 | c.1550G>C p.C517S | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV60050390; called by muse, mutect2, varscan2
- VWA3A | c.2619del p.K873Nfs*2 | Frame Shift Del (DEL) | VAF 27/258 reads (10%) | catalogued as rs1567222967, COSV100240482; called by mutect2, pindel, varscan2
- VWA5A | c.1019+1G>A p.X340_splice | Splice Site (SNP) | VAF 39/364 reads (11%) | catalogued as rs748858579, COSV63707375, COSV63707425; called by muse, mutect2, varscan2
- WDR17 | c.1403A>G p.K468R | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54585794; called by muse, mutect2, varscan2
- WDR7 | c.3140T>C p.I1047T | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs772691042, COSV54347109; called by muse, mutect2, varscan2
- WNK3 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 31/361 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV63616240; called by muse, mutect2
- ZBED9 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.885); catalogued as rs1240047379, COSV71729257; called by muse, mutect2, varscan2
- ZNF292 | c.8031C>A p.C2677* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV100370129; called by muse, mutect2, varscan2
- ZNF347 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100498198; called by muse, mutect2
- ZNF766 | c.1359G>C p.W453C | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63010444; called by muse, mutect2, varscan2
- ZNF92 | c.1012del p.E338Kfs*24 (on ENST00000328747 / NM_152626.4; = p.E269Kfs*24 on NM_007139.4) | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as COSV100165966; called by mutect2, pindel
- ZSWIM4 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs1303874483, COSV54324751; called by muse, mutect2, varscan2
- ZUP1 | c.671-1G>T p.X224_splice | Splice Site (SNP) | VAF 14/202 reads (7%) | catalogued as COSV63944924; called by muse, mutect2
- ACTR3B | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- APOL3 | c.1099dup p.A367Gfs*7 (on ENST00000349314 / NM_145640.2; = p.A296Gfs*7 on NM_014349.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4226del p.L1409* | Frame Shift Del (DEL) | VAF 47/286 reads (16%) | called by mutect2, pindel, varscan2
- COBL | c.3712del p.R1238Gfs*4 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel
- GBA3 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2
- PABPC4 | c.880del p.V294* | Frame Shift Del (DEL) | VAF 17/149 reads (11%) | called by mutect2, pindel, varscan2
- PCDH15 | c.2004del p.I669Ffs*2 | Frame Shift Del (DEL) | VAF 19/171 reads (11%) | called by mutect2, pindel, varscan2
- PPIL1 | c.56G>T p.S19I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SGSM1 | c.1603dup p.L535Pfs*6 | Frame Shift Ins (INS) | VAF 18/180 reads (10%) | called by mutect2, varscan2
- TERF2IP | c.1016del p.N339Ifs*12 | Frame Shift Del (DEL) | VAF 12/129 reads (9%) | called by mutect2, pindel
- TMEM161B | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- TUT7 | c.3642dup p.D1215* | Frame Shift Ins (INS) | VAF 54/367 reads (15%) | called by mutect2, varscan2
- USP36 | c.2064del p.K688Nfs*35 | Frame Shift Del (DEL) | VAF 26/135 reads (19%) | called by mutect2, pindel, varscan2
- ADCY2 | c.3210C>T p.D1070= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs1198524822, COSV57860210; called by muse, mutect2
- ADRM1 | c.657A>G p.S219= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as COSV99438890; called by muse, mutect2
- ALMS1 | c.1542T>C p.L514= | Silent (SNP) | VAF 34/446 reads (8%) | catalogued as COSV100041796; called by muse, mutect2
- AMOTL1 | c.1269C>T p.A423= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs776044957, COSV58571479; called by muse, mutect2, varscan2
- ANK1 | c.219G>A p.T73= | Silent (SNP) | VAF 33/209 reads (16%) | catalogued as rs925701582, COSV99224604; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOD | c.567G>A p.S189= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as rs200510277, COSV58402895; called by muse, mutect2, varscan2
- ARHGAP35 | c.3318C>T p.S1106= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs1264809704, COSV68331790; called by muse, mutect2, varscan2
- ARHGEF7 | c.1596A>G p.T532= (on ENST00000375741 / NM_001113511.2; = p.T354= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV54553169; called by muse, mutect2
- C11orf24 | c.87C>T p.V29= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV58506689; called by muse, mutect2
- CLSTN2 | c.2080T>C p.L694= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV71725649; called by muse, mutect2, varscan2
- CROCC | c.1134G>A p.E378= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV65015298; called by muse, mutect2, varscan2
- DCAF12L2 | c.1245C>T p.D415= | Silent (SNP) | VAF 19/242 reads (8%) | catalogued as rs753659766, COSV63581096; called by muse, mutect2
- DCDC1 | c.483G>A p.Q161= | Silent (SNP) | VAF 51/299 reads (17%) | catalogued as COSV60861262; called by muse, mutect2, varscan2
- DHX40 | c.147T>C p.T49= | Silent (SNP) | VAF 34/246 reads (14%) | catalogued as COSV52070381; called by muse, mutect2, varscan2
- DISP1 | c.2736G>A p.P912= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as rs745813263, COSV52665984; called by muse, mutect2, varscan2
- DPAGT1 | c.798C>T p.G266= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV99597873; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1416G>T p.G472= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV99818040; called by muse, mutect2
- ERBIN | c.3339G>T p.A1113= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV52320019, COSV52328787; called by muse, mutect2, varscan2
- ERBIN | c.3426T>C p.P1142= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV52328823; called by muse, mutect2
- FAM210B | c.300C>T p.G100= | Silent (SNP) | VAF 39/404 reads (10%) | catalogued as rs1371656528, COSV57168688; called by muse, mutect2
- FCRL3 | c.1788C>T p.Y596= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs566843294, COSV63843110; called by muse, mutect2, varscan2
- GLRA2 | c.124C>T p.L42= | Silent (SNP) | VAF 65/722 reads (9%) | catalogued as rs751025273, COSV54348421, COSV99491794; called by muse, mutect2
- GPR162 | c.1632G>A p.E544= (on ENST00000311268 / NM_019858.2; = p.E260= on NM_014449.2) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs781896144, COSV51836897; called by muse, varscan2
- HCN4 | c.1908G>A p.Q636= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV56088290; called by muse, mutect2, varscan2
- IRX1 | c.1191C>A p.P397= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100116877, COSV57362991; called by muse, mutect2, varscan2
- JAKMIP2 | c.471G>A p.A157= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as rs781526933, COSV54617044; called by muse, mutect2, varscan2
- KRT28 | c.753G>A p.P251= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1198821641, COSV60684838; called by muse, mutect2, varscan2
- LRBA | c.4947T>C p.N1649= | Silent (SNP) | VAF 40/214 reads (19%) | catalogued as rs200578734, COSV63966622; called by muse, mutect2, varscan2
- NDRG3 | c.315A>T p.P105= (on ENST00000349004 / NM_032013.4; = p.P93= on NM_022477.4) | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV62423880; called by muse, mutect2, varscan2
- PCDH11X | c.2922C>A p.A974= | Silent (SNP) | VAF 52/558 reads (9%) | catalogued as COSV53511259; called by muse, mutect2
- PCDH18 | c.2262T>C p.I754= | Silent (SNP) | VAF 59/346 reads (17%) | catalogued as COSV100787166; called by muse, mutect2, varscan2
- PCDHB5 | c.2250C>T p.Y750= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs374460300, COSV50676756; called by muse, mutect2
- PCDHGB1 | c.195G>T p.R65= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs1039998570, COSV54049749; called by muse, mutect2, varscan2
- PCLO | c.1890G>A p.T630= | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as rs766820629, COSV61637666; called by muse, mutect2
- PCMTD2 | c.852C>A p.R284= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV55061920, COSV55063144; called by muse, mutect2, varscan2
- PDE8B | c.1968C>T p.D656= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs200042717, COSV53742679, COSV53747001; called by muse, mutect2, varscan2
- PHYKPL | c.744C>A p.I248= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV57425403, COSV57426895; called by muse, mutect2, varscan2
- PKHD1L1 | c.3381A>G p.G1127= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV65736804; called by muse, mutect2
- RBM4B | c.960C>T p.Y320= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs763719303, COSV59496441; called by muse, mutect2, varscan2
- SDK1 | c.1999C>T p.L667= | Silent (SNP) | VAF 15/308 reads (5%) | catalogued as COSV67393939; called by muse, mutect2
- SGTB | c.78G>T p.S26= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV66767436; called by muse, mutect2, varscan2
- SLC24A1 | c.2019G>A p.Q673= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99978144; called by muse, mutect2, varscan2
- SMARCC1 | c.930T>C p.S310= | Silent (SNP) | VAF 18/211 reads (9%) | catalogued as COSV99592547; called by muse, mutect2
- SPOCD1 | c.3222C>A p.G1074= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV57100692; called by muse, mutect2, varscan2
- SUN2 | c.474C>T p.A158= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1211809169, COSV53307507; ClinVar: likely benign; called by muse, mutect2, varscan2
- TANC1 | c.5301T>C p.T1767= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99713405; called by muse, mutect2
- TDO2 | c.774G>A p.Q258= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV72483948; called by muse, mutect2, varscan2
- TNNT2 | c.180G>A p.E60= | Silent (SNP) | VAF 48/470 reads (10%) | catalogued as COSV52665639; called by muse, mutect2
- TRIM67 | c.1017G>A p.P339= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs117065429, COSV100792077; called by mutect2, varscan2
- TUSC3 | c.756T>C p.R252= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV101140920; called by muse, mutect2
- ZNF292 | c.243T>C p.A81= | Silent (SNP) | VAF 65/308 reads (21%) | catalogued as rs1209672952, COSV100370127; called by muse, mutect2, varscan2
- ZNF500 | c.1062G>A p.K354= | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as COSV54790327; called by muse, mutect2, varscan2
- ZNF556 | c.888C>T p.Y296= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100298985, COSV56914619; called by muse, mutect2, varscan2
- MIR31 | n.55C>T | RNA (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- NRG1 | c.502+30953C>A | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99828099; called by mutect2, varscan2
- SSPOP | n.14153G>A | RNA (SNP) | VAF 32/94 reads (34%) | catalogued as rs551457534, COSV65130992; called by muse, mutect2, varscan2
- TOR2A | c.593+34G>A | Intron (SNP) | VAF 7/53 reads (13%) | catalogued as rs995990413, COSV59130823; called by muse, mutect2, varscan2
